Somatic mutation profile of tumor specimen ER-B0GF-TTM1-A (aliquot ER-B0GF-TTM1-A-1-0-D-A697-34) from EXCEPTIONAL_RESPONDERS case ER-B0GF, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders). Sex at birth: female; Vital status: Alive; Tissue or organ of origin: Breast, NOS.
Specimen ER-B0GF-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 14bdda45-1f89-4ffb-a1c3-b79a5d99c35b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ER-B0GF-NT1-A (Solid Tissue Normal), aliquot ER-B0GF-NT1-A-1-0-D-A697-34; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f18aae45-aad4-4e3c-85c1-0e8671cdd13b

The open-access MAF lists 158 somatic variants for this specimen: 115 protein-altering or splice-affecting, 34 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 97, Silent 34, Nonsense Mutation 6, Frame Shift Del 5, In Frame Del 5, 3'UTR 4, RNA 3, Intron 1, Nonstop Mutation 1, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 90/269 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.375+1G>A p.X125_splice | Splice Site (SNP) | VAF 19/42 reads (45%) | hotspot (GDC flag); catalogued as rs1567555445, CS951538, COSV52663569, COSV52668477, COSV52702628; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- ABCC9 | c.3805T>G p.L1269V | Missense Mutation (SNP) | VAF 31/246 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.186); catalogued as COSV53978035, COSV99687670; called by muse, mutect2, varscan2
- ADGB | c.503T>G p.L168R | Missense Mutation (SNP) | VAF 36/216 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.202); catalogued as COSV100484445; called by muse, mutect2, varscan2
- ANO3 | c.1658G>T p.G553V | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.985); catalogued as COSV56795588; called by muse, mutect2, varscan2
- ARMC4 | c.26C>T p.T9M | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs181484327, COSV100536459; ClinVar: uncertain significance; called by muse, varscan2
- CCDC168 | c.5527G>T p.D1843Y | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV70555890; called by muse, mutect2, varscan2
- EPB42 | c.1574A>C p.K525T (on ENST00000441366 / NM_001114134.2; = p.K555T on NM_000119.3) | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV55750649; called by muse, mutect2
- EXT2 | c.1832A>G p.K611R (on ENST00000343631; = p.K644R on NM_000401.3) | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT tolerated (0.46); PolyPhen benign (0.028); catalogued as rs1166871577; called by muse, mutect2, varscan2
- HCFC1 | c.3938C>T p.A1313V | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as COSV60069604; called by muse, mutect2, varscan2
- HERC2 | c.9166G>A p.G3056S | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV55305733; called by muse, mutect2, varscan2
- HS3ST2 | c.434C>T p.T145M | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs774151257, COSV99757696; called by muse, mutect2, varscan2
- JUP | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs782761197; called by muse, mutect2
- KCNA4 | c.205G>A p.G69R | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.435); catalogued as rs1270318199, COSV100068784, COSV60254907; called by mutect2, varscan2
- KIF2B | c.628del p.Q210Kfs*9 | Frame Shift Del (DEL) | VAF 13/19 reads (68%) | catalogued as COSV52136335; called by mutect2, pindel, varscan2
- LAIR1 | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as rs758156418; called by muse, mutect2, varscan2
- LMOD2 | c.1194G>T p.W398C | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs1175271580; called by muse, mutect2, varscan2
- MIB2 | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs879095175; called by muse, mutect2, varscan2
- MTMR8 | c.1301G>C p.C434S | Missense Mutation (SNP) | VAF 130/467 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as COSV66392388; called by muse, mutect2, varscan2
- MTX1 | c.794C>A p.T265N | Missense Mutation (SNP) | VAF 78/157 reads (50%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.586); catalogued as COSV57427846; called by muse, mutect2, varscan2
- NELL1 | c.1020A>C p.K340N | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.787); catalogued as COSV54236708, COSV54263958; called by muse, mutect2, varscan2
- NLRP5 | c.73C>G p.L25V | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.355); catalogued as COSV101173728; called by muse, mutect2, varscan2
- OR13C4 | c.957A>C p.*319Yext*? | Nonstop Mutation (SNP) | VAF 10/99 reads (10%) | catalogued as COSV52928069, COSV99470294; called by muse, mutect2, varscan2
- OR2T3 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as rs558628738, COSV62083981; called by muse, mutect2, varscan2
- OR9G4 | c.115T>A p.L39M | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.122); catalogued as COSV57247445; called by muse, mutect2, varscan2
- PERM1 | c.545G>A p.R182Q | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1037755807; called by muse, mutect2, varscan2
- PGAM4 | c.61C>T p.R21C | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.043); catalogued as rs199995586, COSV100430797; called by muse, mutect2, varscan2
- PRPF31 | c.1484G>T p.G495V | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.022); catalogued as COSV58087724; called by muse, mutect2
- RC3H2 | c.1484G>C p.G495A | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs1489793117; called by muse, mutect2, varscan2
- RIMS1 | c.430G>A p.G144R | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53460755; called by muse, mutect2
- RP1 | c.3461C>T p.T1154I | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs868591794; called by muse, mutect2, varscan2
- SAMD9 | c.1135A>T p.K379* | Nonsense Mutation (SNP) | VAF 79/152 reads (52%) | catalogued as rs572262935; called by muse, mutect2, varscan2
- SCNN1G | c.1468C>T p.R490W | Missense Mutation (SNP) | VAF 41/152 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); catalogued as rs72647530; called by muse, mutect2, varscan2
- TEP1 | c.6820A>G p.T2274A | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs1166162439; called by muse, mutect2
- TTN | c.23313A>C p.E7771D (on ENST00000591111; = p.E6844D on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/116 reads (25%) | PolyPhen benign (0.009); catalogued as COSV60315445; called by muse, mutect2, varscan2
- TTN | c.21716G>A p.R7239H (on ENST00000591111; = p.R6312H on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/142 reads (21%) | PolyPhen possibly damaging (0.624); catalogued as rs374344734, COSV60020757; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUB | c.1379G>T p.G460V (on ENST00000299506 / NM_177972.3; = p.G515V on NM_003320.4) | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.219); catalogued as COSV55110030; called by muse, mutect2, varscan2
- UBASH3B | c.1007C>T p.S336L | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs764567903, COSV52502572; called by muse, mutect2, varscan2
- UNC80 | c.5321C>T p.P1774L | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.039); catalogued as rs1029859784, COSV55909921; called by muse, mutect2, varscan2
- ZNF479 | c.266C>T p.T89M | Missense Mutation (SNP) | VAF 93/165 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs782731688; called by muse, mutect2, varscan2
- ZNF707 | c.211C>T p.R71W | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs782022012; called by muse, mutect2, varscan2
- AASDH | c.2843C>A p.S948* | Nonsense Mutation (SNP) | VAF 45/277 reads (16%) | called by muse, mutect2, varscan2
- AMPH | c.236A>G p.E79G | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2
- ANO3 | c.2141C>T p.P714L | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- APOBEC3F | c.109T>A p.Y37N | Missense Mutation (SNP) | VAF 14/340 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- APOE | c.368G>C p.G123A | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0.023); called by muse, mutect2
- ARHGAP5 | c.2521G>T p.G841* | Nonsense Mutation (SNP) | VAF 65/198 reads (33%) | called by muse, mutect2, varscan2
- ARID1B | c.2521T>G p.S841A | Missense Mutation (SNP) | VAF 51/366 reads (14%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- BBS9 | c.801C>A p.N267K | Missense Mutation (SNP) | VAF 30/179 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- C3 | c.1528C>T p.P510S | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0.034); called by muse, mutect2
- CAPN7 | c.922A>T p.K308* | Nonsense Mutation (SNP) | VAF 36/118 reads (31%) | called by muse, mutect2, varscan2
- CCDC198 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.414); called by muse, mutect2, varscan2
- CNTN1 | c.2045T>C p.V682A | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- CR1 | c.4766A>G p.N1589S | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CWF19L1 | c.922G>T p.D308Y | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- DROSHA | c.1976T>G p.L659* | Nonsense Mutation (SNP) | VAF 478/1356 reads (35%) | called by muse, mutect2, varscan2
- DTNA | c.535A>C p.T179P | Missense Mutation (SNP) | VAF 24/188 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); called by muse, mutect2
- EDEM2 | c.1153G>T p.G385W | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- FAM83C | c.973C>A p.P325T | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- FAT3 | c.9411C>A p.N3137K | Missense Mutation (SNP) | VAF 42/113 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- FAT4 | c.2270C>A p.T757K | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FLG | c.7237T>C p.S2413P | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by muse, mutect2
- FLT1 | c.1903G>C p.A635P | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- FNDC1 | c.4324A>G p.K1442E | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- FOLH1 | c.1272A>C p.E424D | Missense Mutation (SNP) | VAF 174/857 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GJA10 | c.1084A>T p.N362Y | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- GPRIN3 | c.146_157del p.G49_A52del | In Frame Del (DEL) | VAF 4/20 reads (20%) | called by mutect2, varscan2
- GTF2IRD1 | c.2128C>A p.Q710K (on ENST00000265755 / NM_016328.3; = p.Q695K on NM_005685.4) | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); called by muse, mutect2
- GTF2IRD1 | c.2129A>G p.Q710R (on ENST00000265755 / NM_016328.3; = p.Q695R on NM_005685.4) | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- HIVEP2 | c.1532C>G p.S511C | Missense Mutation (SNP) | VAF 27/228 reads (12%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- HYOU1 | c.145A>T p.I49F | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KALRN | c.8264T>G p.L2755R (on ENST00000360013 / NM_001024660.4; = p.L1058R on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNH7 | c.763A>T p.S255C | Missense Mutation (SNP) | VAF 31/177 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- L3MBTL1 | c.455A>G p.D152G (on ENST00000418998 / NM_001377303.1; = p.D62G on NM_015478.7) | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MARCHF9 | c.424C>G p.R142G | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- MTMR12 | c.1667G>C p.R556P | Missense Mutation (SNP) | VAF 29/170 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC16 | c.3994G>T p.D1332Y | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- MYOC | c.278G>T p.S93I | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- NKAPL | c.146A>G p.E49G | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- NOS1 | c.134_148del p.D45_G49del | In Frame Del (DEL) | VAF 13/30 reads (43%) | called by mutect2, pindel, varscan2
- OR4F15 | c.102C>G p.F34L | Missense Mutation (SNP) | VAF 70/202 reads (35%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- OR6N2 | c.427A>T p.K143* | Nonsense Mutation (SNP) | VAF 47/94 reads (50%) | called by muse, mutect2, varscan2
- OTULIN | c.799A>G p.N267D | Missense Mutation (SNP) | VAF 108/342 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PARD3 | c.2167G>A p.E723K | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- PCDHB7 | c.2242C>A p.Q748K | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.399); called by muse, mutect2, varscan2
- PLEK | c.141G>C p.M47I | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- PSMF1 | c.253G>T p.V85L | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.048); called by muse, varscan2
- PYGM | c.1544A>T p.D515V | Missense Mutation (SNP) | VAF 27/41 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- RAD21L1 | c.524T>G p.I175R | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.308); called by muse, mutect2, varscan2
- RALGAPB | c.3259_3263del p.R1087Ffs*3 | Frame Shift Del (DEL) | VAF 19/142 reads (13%) | called by pindel, varscan2
- RASGRP3 | c.63del p.M22Cfs*16 | Frame Shift Del (DEL) | VAF 25/106 reads (24%) | called by mutect2, pindel, varscan2
- RASSF2 | c.824A>G p.Y275C | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ROS1 | c.5487_5534del p.R1829_I1844del | In Frame Del (DEL) | VAF 16/154 reads (10%) | called by mutect2, pindel
- SF3B2 | c.67C>A p.H23N | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- SHMT2 | c.1425C>A p.D475E | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- SLC10A6 | c.165C>G p.I55M | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- SLC15A4 | c.1507G>C p.G503R | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SOCS5 | c.482T>C p.V161A | Missense Mutation (SNP) | VAF 41/200 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- TCERG1 | c.3207del p.K1069Nfs*2 | Frame Shift Del (DEL) | VAF 14/102 reads (14%) | called by mutect2, pindel, varscan2
- TFPT | c.193G>C p.E65Q | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- TJP1 | c.4166C>T p.S1389F | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- TLR4 | c.559_566del p.I187Yfs*35 (on ENST00000355622 / NM_138554.5; = p.I147Yfs*35 on NM_003266.4) | Frame Shift Del (DEL) | VAF 25/91 reads (27%) | called by mutect2, pindel, varscan2
- TRAF3IP1 | c.601_642del p.K201_E214del | In Frame Del (DEL) | VAF 55/137 reads (40%) | called by mutect2, pindel
- TTN | c.72366_72383del p.Q24122_F24128delinsH (on ENST00000591111; = p.Q16698_F16704delinsH on NM_003319.4) | In Frame Del (DEL) | VAF 8/70 reads (11%) | called by mutect2, pindel, varscan2
- TTN | c.5939A>G p.K1980R (on ENST00000591111; = p.K1934R on NM_003319.4) | Missense Mutation (SNP) | VAF 31/136 reads (23%) | PolyPhen benign (0.028); called by muse, mutect2, varscan2
- UBIAD1 | c.728C>G p.A243G | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- UBL7 | c.473G>C p.G158A | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- USP11 | c.496C>G p.L166V (on ENST00000218348; = p.L123V on NM_001371072.1) | Missense Mutation (SNP) | VAF 23/31 reads (74%) | SIFT deleterious (0); PolyPhen benign (0.362); called by muse, mutect2, varscan2
- USP24 | c.2366T>G p.F789C | Missense Mutation (SNP) | VAF 87/298 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- VIP | c.141T>A p.N47K | Missense Mutation (SNP) | VAF 40/353 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.079); called by muse, mutect2
- VIP | c.143A>G p.E48G | Missense Mutation (SNP) | VAF 39/358 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2
- VWC2L | c.173G>T p.G58V | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZBTB21 | c.1109G>C p.S370T | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZDHHC14 | c.1093A>C p.S365R | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- ZNF284 | c.163G>T p.D55Y | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABHD1 | c.990C>T p.P330= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as rs1304483404; called by muse, mutect2, varscan2
- ACBD5 | c.303T>G p.A101= (on ENST00000375888 / NM_001352568.1; = p.A103= on NM_145698.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 23/94 reads (24%) | called by muse, mutect2, varscan2
- ACP4 | c.1110G>T p.R370= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as COSV54518559; called by muse, mutect2, varscan2
- AKIP1 | c.183A>G p.K61= | Silent (SNP) | VAF 17/40 reads (43%) | called by muse, mutect2, varscan2
- ARHGEF17 | c.4122G>A p.Q1374= | Silent (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2
- ATM | c.7044G>A p.T2348= | Silent (SNP) | VAF 52/139 reads (37%) | catalogued as rs140104789; ClinVar: conflicting interpretations of pathogenicity / benign / likely benign; called by muse, mutect2, varscan2
- C1orf226 | c.771C>T p.S257= | Silent (SNP) | VAF 4/13 reads (31%) | called by muse, mutect2, varscan2
- DENND5A | c.15C>T p.G5= | Silent (SNP) | VAF 4/11 reads (36%) | called by muse, mutect2, varscan2
- DMBT1 | c.6501T>A p.I2167= (on ENST00000338354 / NM_001377530.1; = p.I1410= on NM_004406.3) | Silent (SNP) | VAF 47/87 reads (54%) | called by muse, mutect2, varscan2
- DST | c.5199A>T p.T1733= | Silent (SNP) | VAF 24/107 reads (22%) | called by muse, mutect2, varscan2
- EDEM2 | c.1152G>C p.T384= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as rs377343828; called by muse, mutect2, varscan2
- EDN3 | c.469T>C p.L157= | Silent (SNP) | VAF 8/41 reads (20%) | called by muse, mutect2, varscan2
- EZHIP | c.792A>G p.P264= | Silent (SNP) | VAF 8/44 reads (18%) | called by muse, mutect2, varscan2
- GLI3 | c.4521T>C p.D1507= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as rs141759179; called by muse, mutect2, varscan2
- GPR179 | c.1167G>A p.Q389= (on ENST00000621958; = p.Q388= on NM_001004334.4) | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs533872919; called by muse, mutect2, varscan2
- H2BC15 | c.90C>G p.R30= | Silent (SNP) | VAF 22/74 reads (30%) | called by muse, mutect2, varscan2
- HECTD3 | c.492G>A p.Q164= | Silent (SNP) | VAF 11/17 reads (65%) | called by muse, mutect2, varscan2
- HMGCS2 | c.522C>T p.F174= | Silent (SNP) | VAF 31/103 reads (30%) | called by muse, mutect2, varscan2
- HMGCS2 | c.423C>G p.V141= | Silent (SNP) | VAF 20/75 reads (27%) | called by muse, mutect2, varscan2
- ITIH2 | c.180G>C p.S60= | Silent (SNP) | VAF 13/90 reads (14%) | catalogued as COSV64433473; called by muse, mutect2, varscan2
- JMJD1C | c.6844T>C p.L2282= | Silent (SNP) | VAF 32/98 reads (33%) | catalogued as rs1349303677; called by muse, mutect2, varscan2
- KPRP | c.201T>C p.S67= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV64223077; called by muse, mutect2, varscan2
- LPA | c.3768C>A p.S1256= | Silent (SNP) | VAF 37/199 reads (19%) | called by muse, mutect2, varscan2
- MTHFD1 | c.819C>G p.G273= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV99387169; called by muse, mutect2, varscan2
- MVB12B | c.282G>A p.L94= | Silent (SNP) | VAF 8/50 reads (16%) | called by muse, mutect2
- NEO1 | c.2001T>G p.T667= | Silent (SNP) | VAF 10/35 reads (29%) | called by muse, mutect2, varscan2
- OBSCN | c.20361T>G p.G6787= | Silent (SNP) | VAF 5/17 reads (29%) | called by muse, mutect2, varscan2
- PDE2A | c.2151G>A p.A717= | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as rs146881776; called by muse, mutect2, varscan2
- PLXDC2 | c.162G>A p.V54= | Silent (SNP) | VAF 33/154 reads (21%) | catalogued as rs777499298; called by muse, mutect2, varscan2
- PTH2 | c.270C>T p.Y90= | Silent (SNP) | VAF 20/49 reads (41%) | called by muse, mutect2, varscan2
- SLC17A7 | c.1116C>T p.S372= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as rs1568634061; called by muse, mutect2
- TENM2 | c.4299G>A p.E1433= (on ENST00000518659 / NM_001122679.2; = p.E1194= on NM_001080428.3) | Silent (SNP) | VAF 22/109 reads (20%) | called by muse, mutect2, varscan2
- TRIM42 | c.498C>T p.C166= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs756270365, COSV53879972; called by muse, mutect2, varscan2
- ZNF831 | c.399C>A p.G133= | Silent (SNP) | VAF 14/33 reads (42%) | called by muse, mutect2, varscan2
- AGTR1 | c.*68C>T | 3'UTR (SNP) | VAF 20/92 reads (22%) | called by muse, mutect2, varscan2
- C20orf197 | n.400C>G | RNA (SNP) | VAF 78/188 reads (41%) | called by muse, mutect2, varscan2
- HDGFL1 | c.*679C>T | 3'UTR (SNP) | VAF 20/35 reads (57%) | called by muse, mutect2, varscan2
- HTR1F | c.*949T>A | 3'UTR (SNP) | VAF 162/505 reads (32%) | called by muse, mutect2, varscan2
- IKBKE | c.1836-470C>T | Intron (SNP) | VAF 66/117 reads (56%) | catalogued as rs782192059; called by muse, mutect2, varscan2
- MIR325 | n.97G>A | RNA (SNP) | VAF 64/290 reads (22%) | called by muse, varscan2
- MIR325 | n.48_50del | RNA (DEL) | VAF 70/338 reads (21%) | called by pindel, varscan2
- NANOS2 | c.-43C>A | 5'UTR (SNP) | VAF 10/20 reads (50%) | called by muse, mutect2, varscan2
- RGS9BP | c.*710C>T | 3'UTR (SNP) | VAF 10/22 reads (45%) | catalogued as COSV60134398; called by muse, mutect2, varscan2
